MMRF case MMRF_2132 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/c62f3da1-3ec4-46fb-8981-28a005a52655

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 87 years; Vital status: Dead; Days to death: 195 days; Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 87.6 years (32,005 days); ISS stage: II; Days to last known disease status: 195 days; Days to last follow up: 195 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 134 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 195.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -74 (ECOG 0): M Protein 2.6 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.842 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 107 mg/dL; Immunoglobulin G 45.4 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 6.81 ×10⁹/L; Absolute Neutrophil 3.53 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.1 mmol/L; Albumin 29 g/L; Total Protein 8.8 g/dL; Glucose 4.35 mmol/L.
- Day 22 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.932 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 38.5 mg/dL; Immunoglobulin G 27.3 g/L; Immunoglobulin A 0.19 g/L; Immunoglobulin M 0.06 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 4.29 ×10⁹/L; Absolute Neutrophil 2.48 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.05 mmol/L; Albumin 29 g/L; Total Protein 7.2 g/dL; Glucose 4.51 mmol/L.
- Day 106: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.932 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.45 mg/dL; Immunoglobulin G 9.92 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.34 g/L; Beta 2 Microglobulin 2.2 µg/mL; Hemoglobin 8.06 mmol/L; Leukocytes 5.65 ×10⁹/L; Absolute Neutrophil 3.99 ×10⁹/L; Platelets 287 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.08 mmol/L; Albumin 31 g/L; Total Protein 6.4 g/dL; Glucose 5.28 mmol/L.

Other clinical attributes
- Day -74: Weight: 86 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2132_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -74 days.
- Sample MMRF_2132_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -74 days.
